Gene-level copy-number profile of tumor specimen TCGA-BR-8058-01A from TCGA case TCGA-BR-8058, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.8 years (19,658 days).
Specimen TCGA-BR-8058-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.63abb09b-d5e0-40c5-887a-b6582c11a8c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8058-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9cb54180-4489-4ad7-82d0-31fbf0f6bf91

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,613; copy number 2: 42,707; copy number 3: 1,310; copy number 4: 170; copy number 8: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8058-01A-31D-2338-01): tumor purity 0.3, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:85,683,848–86,423,109, 18 genes, copy number 8: CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81.
- chr11:86,432,098–86,437,282, 2 genes, copy number 8: PTP4A1P6, AP001148.1.

Autosomal genes at a single copy (total copy number 1): 14,401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
